Somatic mutation profile of tumor specimen C3L-00606-03 (aliquot CPT0079290009) from CPTAC case C3L-00606, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.7 years (27,636 days).
Specimen C3L-00606-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa163198-dbce-48b8-b752-8a08f41b0ad9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00606-31 (Blood Derived Normal), aliquot CPT0080110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdcbc821-dd90-47c1-9eae-dd40325d07fa

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 10, Intron 4, Splice Site 3, Nonsense Mutation 2, RNA 2, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1G>C p.X155_splice | Splice Site (SNP) | VAF 73/211 reads (35%) | hotspot (GDC flag); catalogued as rs869025657, CS004297, CS111451, CS961708, COSV56543633, COSV56544194, COSV56546569, COSV56552736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- FAR1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61385256; called by muse, mutect2, varscan2
- GALNTL6 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72552982; called by muse, mutect2, varscan2
- KCNQ5 | c.2707_2708del p.L903Kfs*13 | Frame Shift Del (DEL) | VAF 50/272 reads (18%) | catalogued as rs779394238; called by pindel, varscan2
- KIF3C | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs748213434; called by muse, mutect2, varscan2
- MED1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56127912; called by muse, mutect2, varscan2
- MRC1 | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 61/330 reads (18%) | catalogued as rs1367320854; called by muse, mutect2, varscan2
- PCDH12 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as rs1175979418, COSV99190845; called by muse, mutect2, varscan2
- SLC2A9 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs773926335; called by muse, mutect2, varscan2
- TALDO1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs893159233, COSV59797685; called by muse, mutect2, varscan2
- TAPBPL | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781465778; called by muse, mutect2, varscan2
- TGFBR3 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1440465103, COSV53025131; called by muse, mutect2, varscan2
- YIPF3 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1554131040; called by muse, mutect2, varscan2
- AHCTF1 | c.2170T>A p.L724M (on ENST00000366508; = p.L698M on NM_015446.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHI1 | c.2777A>T p.E926V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANHX | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD42 | c.996C>G p.D332E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANPEP | c.2067_2070del p.E689Dfs*10 | Frame Shift Del (DEL) | VAF 54/214 reads (25%) | called by mutect2, pindel, varscan2
- ATP6V1C1 | c.63del p.K21Nfs*23 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- ATXN10 | c.1213T>C p.C405R | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C1QB | c.519del p.S174Lfs*7 | Frame Shift Del (DEL) | VAF 48/226 reads (21%) | called by mutect2, pindel, varscan2
- C2CD6 | c.244del p.T82Lfs*12 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- CASP4 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CCDC18 | c.2347G>A p.E783K (on ENST00000343253 / NM_001306076.1; = p.E784K on NM_206886.4) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CLCN1 | c.2291G>C p.R764T | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DBN1 | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 140/384 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF7 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DST | c.8029T>A p.L2677I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FBXO25 | c.1056_1068del p.F353Lfs*23 (on ENST00000382824 / NM_183421.2; = p.F277Lfs*23 on NM_012173.3) | Frame Shift Del (DEL) | VAF 17/189 reads (9%) | called by mutect2, pindel
- HECW1 | c.3753-15_3763del p.X1251_splice | Splice Site (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel
- HSPBP1 | c.-94-1G>C | Splice Site (SNP) | VAF 77/338 reads (23%) | called by muse, mutect2, varscan2
- IREB2 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LHX3 | c.290T>A p.I97N (on ENST00000371748 / NM_178138.6; = p.I102N on NM_014564.5) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LINGO4 | c.961del p.H321Mfs*3 | Frame Shift Del (DEL) | VAF 34/189 reads (18%) | called by mutect2, pindel, varscan2
- LYZL2 | c.320C>T p.A107V (on ENST00000375318; = p.A61V on NM_183058.3) | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MROH2B | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NDN | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- NUP160 | c.4039T>G p.L1347V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR13D1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR13D1 | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2G2 | chr1:247589313 del ATT | Missense Mutation (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- PBRM1 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHGA4 | c.1358dup p.T454Nfs*4 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASA2 | c.1686del p.E563Rfs*18 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- SMC4 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SULT4A1 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SV2A | c.619del p.L207* | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- TRIO | c.1386T>G p.D462E | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- TRPC7 | c.2127del p.F709Lfs*3 | Frame Shift Del (DEL) | VAF 19/168 reads (11%) | called by mutect2, pindel, varscan2
- TTLL13P | c.2380C>T p.L794F | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ZNF350 | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BCOR | c.1321C>T p.L441= | Silent (SNP) | VAF 125/571 reads (22%) | catalogued as COSV60702862; called by muse, mutect2, varscan2
- CEP78 | c.1389G>A p.L463= (on ENST00000424347 / NM_001349840.2; = p.L464= on NM_032171.3) | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- CHD9 | c.2946C>T p.G982= | Silent (SNP) | VAF 45/293 reads (15%) | called by muse, mutect2, varscan2
- ECD | c.1032T>C p.D344= | Silent (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- EEF1E1 | c.66C>T p.Y22= | Silent (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- FAT1 | c.7059C>A p.S2353= | Silent (SNP) | VAF 68/279 reads (24%) | called by muse, mutect2, varscan2
- MACF1 | c.7350T>A p.A2450= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- NFATC2 | c.747T>C p.G249= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV65356595; called by muse, mutect2, varscan2
- NRSN1 | c.249C>T p.G83= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs140489181; called by muse, mutect2
- PKHD1 | c.7872A>G p.S2624= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as rs1446607271; called by muse, mutect2, varscan2
- SH2D2A | c.243C>A p.T81= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- STARD8 | c.2523G>C p.V841= | Silent (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.3105C>T p.G1035= (on ENST00000648592; = p.G1001= on NM_182973.2) | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs1300920785; called by muse, mutect2, varscan2
- YIPF3 | c.159G>C p.L53= | Silent (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- COMMD4P1 | n.338A>G | RNA (SNP) | VAF 13/84 reads (15%) | catalogued as rs1403090287; called by muse, mutect2, varscan2
- DOCK6 | c.*23C>T | 3'UTR (SNP) | VAF 37/181 reads (20%) | catalogued as rs753002305; called by muse, mutect2, varscan2
- HUWE1 | c.8206+129G>T | Intron (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- LDHA | c.*480T>C | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- POU2F2 | c.186+25G>A | Intron (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- PSG8 | chr19:42753364 G>A | 3'Flank (SNP) | VAF 40/312 reads (13%) | catalogued as rs758343639; called by muse, mutect2, varscan2
- TCF4 | c.305-26C>A | Intron (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- TUBBP5 | n.1427C>T | RNA (SNP) | VAF 13/70 reads (19%) | catalogued as rs189844666; called by mutect2, varscan2
- WWC1 | c.2917-17dup | Intron (INS) | VAF 33/108 reads (31%) | called by mutect2, pindel, varscan2
